Somatic mutation profile of tumor specimen 0DVZEL from CCDI case PBCMZX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,928 days).
Specimen 0DVZEL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce31e595-f3b2-4d73-9592-181f510b22ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZEC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fbfd832-0eab-4f51-8917-b9dea94cb672

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F2 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 143/795 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.376); catalogued as rs142001812; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A3R1 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 40/786 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.317); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 56/1044 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- IZUMO1 | c.630G>A p.V210= | Silent (SNP) | VAF 116/487 reads (24%) | called by muse, varscan2
- CFLAR | c.606+1015C>T | Intron (SNP) | VAF 20/570 reads (4%) | called by muse, mutect2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 20/741 reads (3%) | called by muse, mutect2
